Somatic mutation profile of tumor specimen TCGA-WC-A880-01A (aliquot TCGA-WC-A880-01A-11D-A39W-08) from TCGA case TCGA-WC-A880, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 63.9 years (23,325 days).
Specimen TCGA-WC-A880-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c01278f-7959-418f-849c-770f8c5f5677.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A880-10A (Blood Derived Normal), aliquot TCGA-WC-A880-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc5a1c4d-3828-4047-8c9c-6f87877d3503

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 27/29 reads (93%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV63309376; called by muse, mutect2, varscan2
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 55/105 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SPHKAP | c.1982A>T p.N661I | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs368321165; called by muse, mutect2, varscan2
- MUC4 | c.15064G>A p.G5022S (on ENST00000463781 / NM_018406.7; = p.G786S on NM_004532.6) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NPAS1 | c.910A>T p.M304L | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- POLR1B | c.2708C>T p.P903L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMC2 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM68 | c.363C>G p.S121R | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CALD1 | c.1362C>T p.D454= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1357556659; called by muse, mutect2, varscan2
- PLSCR5 | c.513C>G p.P171= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV71648912; called by muse, mutect2, varscan2
